Gene-level copy-number profile of tumor specimen ALCH-AEO2-TTP1-A from ALCHEMIST case ALCH-AEO2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.7 years (23,979 days).
Specimen ALCH-AEO2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06209b02-29e7-4297-9cd3-1268c3d418da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEO2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/6007ca8e-1502-439d-8fcf-a76db30e54bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 8,245; copy number 2: 47,605; copy number 3: 949; copy number 4: 1,024; copy number 5: 425; copy number 6: 105; copy number 7: 2; copy number 8: 1; copy number 17: 10.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:219,434,843–219,516,877, 6 genes (within-gene range 0–2): SPEG, ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr4:52,786,537–52,786,638, 1 gene: Y_RNA.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:46,233,885–46,273,557, 1 gene: ANTXRLP1.
- chr16:1,770,286–1,794,971, 6 genes (within-gene range 0–1): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.
- chr20:38,711,821–38,729,372, 2 genes: Metazoa_SRP, SLC32A1.
- chr20:63,540,810–63,556,695, 3 genes: SRMS, AL121829.2, FNDC11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 543 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:167,916,675–167,937,072, 1 gene, copy number 8 (within-gene range 2–8): MPC2.
- chr3:147,939,905–157,533,619, 188 genes, copy number 5–17 (broad region; genes not listed).
- chr3:164,714,095–174,378,005, 136 genes, copy number 5–6 (broad region; genes not listed).
- chr4:49,096–2,625,320, 90 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr4:108,620,566–108,630,412, 1 gene, copy number 5: RPL34.
- chr19:27,638,483–27,646,483, 2 genes, copy number 5: ERVK-28, AC112702.1.
- chr19:57,230,802–58,605,223, 125 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
